Gene-level copy-number profile of tumor specimen TCGA-YU-A94N-01A from TCGA case TCGA-YU-A94N, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 23.0 years (8,416 days).
Specimen TCGA-YU-A94N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6437b4d-192f-4976-8b7f-410ab5c90f46.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-YU-A94N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,756 have no estimate.
https://portal.gdc.cancer.gov/files/8c2e1a7b-6dc1-41ec-8563-18b5544f1c8b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 501; copy number 2: 28,586; copy number 3: 26,228; copy number 4: 1,697; copy number 5: 973; copy number 6: 373; copy number 7: 371; copy number 9: 71; copy number 10: 9.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr16:32,008,438–32,946,392, 52 genes: AC142381.4, IGHV1OR16-1, AC142381.1, IGHV1OR16-3, IGHV3OR16-9, HERC2P4, AC142381.2, AC133485.7, AC133485.6, AC133485.5, AC133485.4, ABHD17AP8, AC133485.1, AC133485.3, TP53TG3D, AC133485.2, AC140878.1, AC133548.2, AC133548.1, ACTR3BP3, AC138915.2, PABPC1P13, AC138915.3, AC138915.1, ABCD1P3, AC137800.1, AC137800.2, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2, AC142086.2, IGHV2OR16-5, BCAP31P2, SLC6A10P, AC142086.1, IGHV3OR16-15, IGHV3OR16-6, AC142086.6, AC142086.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 451 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:31,651,381–32,821,051, 26 genes, copy number 7: AL133247.2, LINC01946, KRT18P52, AK2P2, AL121652.1, MEMO1, DPY30, AL121655.1, SPAST, AL121658.1, SLC30A6, DDX50P1, RNU6-647P, NLRC4, YIPF4, AL133245.1, BIRC6, BIRC6-AS1, AL133243.2, AL133243.3, MIR558, AL133243.1, BIRC6-AS2, AL133243.4, TTC27, MIR4765.
- chr12:280,057–1,918,666, 29 genes, copy number 7 (within-gene range 6–7): KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2.
- chr12:2,812,622–4,662,643, 48 genes, copy number 7 (within-gene range 6–7): ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1.
- chr12:10,358,464–27,972,733, 337 genes, copy number 7–9 (broad region; genes not listed).
- chr12:28,163,298–28,190,738, 2 genes, copy number 9 (within-gene range 5–9): AC022364.1, AC022364.2.
- chr12:38,078,529–38,207,192, 9 genes, copy number 10: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12.

Autosomal genes at a single copy (total copy number 1): 456. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
